MMRF case MMRF_1995 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/275633c2-5aa6-4d7d-9a07-695fc5cffa49

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.6 years (26,526 days); ISS stage: III; Days to last known disease status: 981 days (2.7 years); Days to last follow up: 981 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 41 days; Days to treatment end: 75 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 41 days; Days to treatment end: 145 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 41 days; Days to treatment end: 275 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 76 days; Days to treatment end: 208 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 146 days; Days to treatment end: 275 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 209 days; Days to treatment end: 293 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 460 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 460 days (1.3 years); Days to treatment end: 980 days (2.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 981 days (2.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 0.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 616 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.913 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 8.16 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.7 mmol/L; Albumin 46 g/L; Total Protein 7.2 g/dL; Glucose 5.34 mmol/L; C-Reactive Protein 0.12 mg/dL.
- Day 90 (ECOG 0): M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 21.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 6.38 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 4.02 µkat/L; Hemoglobin 4.96 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 69 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 1.93 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 4.9 mmol/L.
- Day 174 (ECOG 0): M Protein 0.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.45 mg/dL; Immunoglobulin G 6.71 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 3.96 µg/mL; Lactate Dehydrogenase 4.67 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 73 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 6.7 g/dL; Glucose 4.02 mmol/L.
- Day 271 (ECOG 0): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.619 mg/dL; Immunoglobulin G 5.85 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 86 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.03 mmol/L; Albumin 43 g/L; Total Protein 6 g/dL; Glucose 5.06 mmol/L.
- Day 349 (ECOG 0): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 7.59 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 2.57 µg/mL; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 5.28 mmol/L.
- Day 453 (ECOG 0): M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 59.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.127 mg/dL; Immunoglobulin G 7.9 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 3.31 µg/mL; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.1 g/dL; Glucose 5.39 mmol/L.
- Day 534 (ECOG 1): M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.723 mg/dL; Immunoglobulin G 7.45 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.53 g/L; Hemoglobin 5.39 mmol/L; Leukocytes 1.7 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.13 mmol/L; Total Protein 5.3 g/dL; Glucose 5.39 mmol/L.
- Day 630 (ECOG 1): M Protein 0.79 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 26.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.161 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 1.31 g/L; Beta 2 Microglobulin 2.92 µg/mL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.5 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 5.23 mmol/L.
- Day 734 (ECOG 0): M Protein 0.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 7.45 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.54 g/L; Beta 2 Microglobulin 3.87 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2 mmol/L; Albumin 36 g/L; Total Protein 5.9 g/dL; Glucose 4.84 mmol/L.
- Day 797 (ECOG 0): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.896 mg/dL; Immunoglobulin G 4.25 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.49 g/L; Beta 2 Microglobulin 2.83 µg/mL; Lactate Dehydrogenase 4.37 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 83 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 5.3 g/dL; Glucose 4.95 mmol/L.
- Day 910 (ECOG 0): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 5.42 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.49 g/L; Beta 2 Microglobulin 3.5 µg/mL; Lactate Dehydrogenase 4.13 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 4.51 mmol/L.
- Day 981 (ECOG 1): M Protein 0.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 9.27 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.64 g/L; Beta 2 Microglobulin 2.69 µg/mL; Lactate Dehydrogenase 4.13 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 1.95 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 5.17 mmol/L.

Other clinical attributes
- Day 0: Weight: 81 kg; Height: 169 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (3 samples)
- Sample MMRF_1995_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1995_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
- Sample MMRF_1995_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 630 days (1.7 years).
